Gene-level copy-number profile of tumor specimen TCGA-BK-A0CC-01A from TCGA case TCGA-BK-A0CC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.8 years (25,479 days).
Specimen TCGA-BK-A0CC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.60db069d-225d-4113-9ee2-9843e71e7fe0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BK-A0CC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e1dadf1c-2051-4dbf-a3ac-416d22f736f1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 421; copy number 2: 16,825; copy number 3: 22,047; copy number 4: 14,057; copy number 5: 1,488; copy number 6: 3,000; copy number 7: 1,323; copy number 8: 326; copy number 9: 28; copy number 10: 19; copy number 12: 101; copy number 14: 35; copy number 15: 34; copy number 16: 66; copy number 39: 23; copy number 61: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BK-A0CC-01A-21D-A275-01): tumor purity 0.67, ploidy 5.33, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:180,573,464–180,759,038, 2 genes: NDUFB5P1, AC104803.1.
- chr5:93,583,222–94,111,699, 10 genes (within-gene range 0–2): NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,958 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,363,091–153,460,651, 173 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr1:154,325,525–154,351,304, 2 genes, copy number 8 (within-gene range 5–8): ATP8B2, RNU7-57P.
- chr4:94,451,857–94,757,681, 3 genes, copy number 7 (within-gene range 2–7): PDLIM5, AC108067.1, BMPR1B-DT.
- chr6:285,443–351,355, 2 genes, copy number 8: AL365272.1, DUSP22.
- chr6:71,450,834–71,551,643, 3 genes, copy number 8: LINC01626, AL035467.2, AL035467.1.
- chr7:23,298,739–23,311,729, 1 gene, copy number 7: MALSU1.
- chr7:54,542,325–57,074,664, 92 genes, copy number 16–61 (broad region; genes not listed).
- chr7:63,011,463–63,510,165, 35 genes, copy number 14: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2.
- chr8:48,917,598–52,022,974, 29 genes, copy number 7–8: SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3.
- chr8:52,150,820–52,154,892, 1 gene, copy number 8: AC021915.2.
- chr8:61,714,788–116,325,062, 797 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr11:34,049,967–34,052,132, 1 gene, copy number 7: AC090469.1.
- chr15:89,748,661–89,815,401, 4 genes, copy number 7: MESP1, MRPL15P1, MESP2, ANPEP.
- chr16:28,878,405–35,912,516, 446 genes, copy number 7 (broad region; genes not listed).
- chr19:27,638,483–38,426,305, 369 genes, copy number 8–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
